Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4756, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4756-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Patient with h/o right renal mass (right sided); renal cell cancer.

Specimens Submitted:

- 1: SP: Right kidney, ureter and part of adrenal
- 2: SP: Portion of right 11th rib
- 3: SP: Right hilar lymph nodes
- 4: SP: Fat at lower pole of kidney

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV
- THE PATTERN OF GROWTH IS PAPILLARY AND TUBULAR.
- THE TUMOR GREATEST DIAMETER IS 6.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS NOT IDENTIFIED.
- 2) BONE, PORTION OF RIGHT 11TH; BIOPSY:
- GROSSLY UNREMARKABLE. SECTIONS NOT YET READY BECAUSE OF NEED TO DECALCIFY. IF SIGNIFICANT MICROSCOPIC ABNORMALITIES ARE FOUND, AN ADDENDUM REPORT WILL BE ISSUED.
- 3) LYMPH NODES, RIGHT HILUM; BIOPSY:
- BENIGN LYMPH NODE.
- 4) SOFT TISSUE, LOWER POLE OF KIDNEY; BIOPSY:
- BENIGN ADIPOSE TISSUE.

The specimen is received labeled "Right kidney, ureter and part of adrenal". It consists of a kidney with attached perirenal fat and a portion of Gerota's fascia. The entire specimen weighs 250 grams. The entire specimen measures 12 x 7.5 x 4 cm. The kidney itself measures 10.5 x 7 x 3.5 cm. Present in the inferior pole of the kidney, is a friable variegated yellow focally hemorrhagic mass extending from the cortex up to the pelvis measuring 6.5 x 2 x 1.5 cm in greatest dimension. This mass extends up to the renal capsule, pushing the renal capsule, but not protruding through it. The tumor abuts the calyces and the renal pelvis but does not appear to invade them. The portion of ureter attached to the kidney measures 5 cm in length and 0.3 cm

[page 2 of 3]
[REDACTED]

In diameter. The urothelial lining of the ureter is tan and grossly unremarkable. The vascular structures are grossly unremarkable without involvement by tumor. The remainder of the renal parenchyma is grossly unremarkable. No adrenal gland is identified and this information is conveyed to the Surgeon. A portion of the tumor is submitted for [REDACTED]. A photograph of the specimen is taken. Representative sections are submitted.

Summary of sections:

UM – ureteral resection margin

VM – vascular margin

TC – tumor in relations to capsule

TP – tumor in relations to renal pelvis

TN – tumor in relations to normal renal parenchyma

NK – normal kidney

F – perirenal fat with Gerota's fascia

[REDACTED]

2) The specimen is received in formalin, labeled "Portion of right 11th rib". It consists of a portion of rib measuring 7.6 cm in length and 1.2 cm in width and 0.3 cm in thickness. Portions of soft tissue and skeletal muscle are adherant to the rib. Representative sections are submitted. The specimen is decalcified prior to submission.

Summary of sections:

B – bone tissue

[REDACTED]

3) The specimen is received in formalin, labeled "Right hilar lymph nodes". It consists of a single tan lymph node measuring 0.6 x 0.4 x 0.3 cm. The specimen is entirely submitted.

Summary of sections:

LN - lymph nodes

[REDACTED]

4) The specimen is received in formalin, labeled "Fat at lower pole of kidney". It consists of a 3.2 x 1.5 x 0.5 cm aggregate of adipose tissue. The specimen is entirely submitted.

Summary of sections:

F - fat

Summary of Sections:

Part 1: SP: Right kidney, ureter and part of adrenal [REDACTED]

Block	Sect. Site	PCs
1	F	2
1	NK	1
2	TC	2
2	TN	2
2	TP	2
1	UM	1
1	VM	2

Part 2: SP: Portion of right 11th rib [REDACTED]

Block	Sect. Site	PCs
1	B	3

Part 3: SP: Right hilar lymph nodes [REDACTED]

Block	Sect. Site	PCs
1	LN	1

Part 4: SP: Fat at lower pole of kidney [REDACTED]

[page 3 of 3]
Block
2

Sect. Site
F

PCs
3

Source: NCI Genomic Data Commons file b282f21e-019e-4ba8-9807-cd321967e84b (TCGA-BP-4756.3A3C39F8-3F5E-4E36-A0F2-28F502306354.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).